Somatic mutation profile of tumor specimen MP2PRT-PASNJZ-TMP1-A (aliquot MP2PRT-PASNJZ-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASNJZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,348 days).
Specimen MP2PRT-PASNJZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9c20ee4-620c-40da-bb9a-62cd49df2c40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASNJZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASNJZ-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7135ced-3cd1-47d0-b50e-d952bc76b99d

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, 3'UTR 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RARA | c.630G>A p.T210= | Splice Region (SNP) | VAF 35/181 reads (19%) | catalogued as COSV99564989; called by muse, mutect2, varscan2
- IGHV3-64 | c.342_354delinsCCTCG p.Y115Lfs*? | Frame Shift Del (DEL) | VAF 14/76 reads (18%) | called by pindel, varscan2*
- CCDC61 | c.87G>A p.L29= | Silent (SNP) | VAF 85/496 reads (17%) | called by muse, mutect2, varscan2
- LRBA | c.1176C>T p.F392= | Silent (SNP) | VAF 30/203 reads (15%) | called by muse, mutect2, varscan2
- SPAG11B | c.*160G>T | 3'UTR (SNP) | VAF 33/717 reads (5%) | called by muse, mutect2
